Somatic mutation profile of tumor specimen MMRF_2250_1_BM_CD138pos (aliquot MMRF_2250_1_BM_CD138pos_T1_KHS5U_L08800) from MMRF case MMRF_2250, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.4 years (26,087 days).
Specimen MMRF_2250_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b8ad71-1ec2-46f1-bccc-84222b70f48a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2250_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2250_1_PB_Whole_C2_KHS5U_L08785; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8b73511-f112-4e57-b620-1c1c715a2b6b

The open-access MAF lists 106 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 31, Missense Mutation 29, Intron 15, Silent 13, 3'Flank 4, Frame Shift Del 4, 5'UTR 3, RNA 2, Splice Region 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF7IP2 | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs148549701; called by muse, mutect2, varscan2
- BEND4 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.857); catalogued as rs1189574925; called by muse, mutect2, varscan2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2, varscan2
- CAPS2 | c.1319A>G p.H440R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs748456589; called by muse, mutect2, varscan2
- CCDC158 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); catalogued as rs376849991; called by muse, mutect2
- FBRSL1 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV55513966; called by muse, mutect2
- IGHV2-70 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 34/48 reads (71%) | catalogued as rs370713802; called by muse, varscan2
- IGHV2-70 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs374376585; called by muse, varscan2
- INTS5 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs764151484; called by muse, mutect2, varscan2
- KIAA1841 | c.-7C>T | Splice Region (SNP) | VAF 63/387 reads (16%) | catalogued as rs199775675; called by muse, mutect2, varscan2
- OLFML2B | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771550649, COSV54198120; called by muse, mutect2, varscan2
- PYGO2 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1333761689; called by muse, mutect2, varscan2
- SMAD4 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV61686871; called by muse, mutect2, varscan2
- SYCP2 | c.3682C>T p.R1228W | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as rs770144840, COSV62766165; called by muse, mutect2, varscan2
- TRIM47 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1470405814; called by muse, mutect2, varscan2
- VPS51 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV99659679; called by muse, mutect2
- ZNF85 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV60214238, COSV60215216; called by muse, mutect2, varscan2
- ADAMTS2 | c.2209+2T>G p.X737_splice | Splice Site (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- ASB17 | c.679A>C p.K227Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- CCDC7 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CD19 | c.1492T>A p.S498T (on ENST00000324662 / NM_001178098.2; = p.S497T on NM_001770.6) | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLUL1 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE8 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.5041A>C p.S1681R | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HRC | c.1728del p.L577Wfs*? | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | called by mutect2, pindel, varscan2
- IGHA1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- IGHV2-70 | c.128_150del p.F43* | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- KCNU1 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
- KIAA1328 | c.1421T>G p.V474G | Missense Mutation (SNP) | VAF 133/265 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA6 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NEDD4 | c.3815A>C p.E1272A (on ENST00000508342 / NM_001284338.1; = p.E853A on NM_006154.4) | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- P3H4 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- RASA2 | c.772_794del p.W258Rfs*6 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- SCAF4 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC24A3 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TMPRSS11E | c.1132_1141del p.V378Mfs*11 | Frame Shift Del (DEL) | VAF 15/119 reads (13%) | called by mutect2, pindel, varscan2
- TOPAZ1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VWA8 | c.1212G>A p.K404= | Splice Region (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ANK2 | c.6066A>G p.Q2022= | Silent (SNP) | VAF 94/207 reads (45%) | called by muse, mutect2, varscan2
- CAPN13 | c.735G>A p.L245= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CHD6 | c.5319C>T p.N1773= | Silent (SNP) | VAF 79/146 reads (54%) | catalogued as rs766111590; called by muse, mutect2, varscan2
- DIP2C | c.3942C>T p.D1314= | Silent (SNP) | VAF 90/205 reads (44%) | catalogued as COSV55183769; called by muse, mutect2, varscan2
- EPB41L5 | c.1212C>T p.G404= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1485028242, COSV55350582; called by muse, mutect2, varscan2
- KCNC2 | c.66C>T p.Y22= | Silent (SNP) | VAF 107/230 reads (47%) | catalogued as rs759469657; called by muse, mutect2, varscan2
- KCNU1 | c.2853C>T p.C951= | Silent (SNP) | VAF 151/301 reads (50%) | called by muse, mutect2, varscan2
- OR2A4 | c.801G>A p.K267= | Silent (SNP) | VAF 78/193 reads (40%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1422A>G p.P474= | Silent (SNP) | VAF 23/138 reads (17%) | called by muse, varscan2
- SPEN | c.8121C>T p.L2707= | Silent (SNP) | VAF 59/132 reads (45%) | called by muse, mutect2, varscan2
- TMEM121B | c.1266G>T p.A422= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as rs1275914455; called by muse, mutect2, varscan2
- ZBTB21 | c.2178C>T p.L726= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs1219378230; called by muse, mutect2, varscan2
- ZNF503 | c.1458G>A p.A486= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs1020124449, COSV65306975; called by muse, mutect2, varscan2
- ADH1B | c.*1096T>C | 3'UTR (SNP) | VAF 17/101 reads (17%) | catalogued as rs1249485536; called by muse, mutect2, varscan2
- AFF2 | c.*4793A>T | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.*226G>A | 3'UTR (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- BCKDHB | c.*511T>G | 3'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- C3orf14 | chr3:62335935 A>C | 3'Flank (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.*277G>A | 3'UTR (SNP) | VAF 91/173 reads (53%) | called by muse, mutect2, varscan2
- CCNYL1 | c.*1629C>A | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- CEP295 | c.7303-33_7303-31del | Intron (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- CEP78 | c.*1552C>G | 3'UTR (SNP) | VAF 25/26 reads (96%) | catalogued as rs1419773139; called by muse, mutect2, varscan2
- COLEC11 | c.*311T>C | 3'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- CSPG4P13 | n.1823G>A | RNA (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- CTTN | c.679+171G>T | Intron (SNP) | VAF 72/139 reads (52%) | called by muse, mutect2, varscan2
- DENND5B | c.128-4604A>G | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs1457661216; called by muse, mutect2, varscan2
- DOK7 | c.*810G>C | 3'UTR (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- EGR1 | c.-75C>T | 5'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- EMP2 | c.*696C>A | 3'UTR (SNP) | VAF 61/108 reads (56%) | catalogued as rs562560540; called by mutect2, varscan2
- EYA4 | chr6:133531653 T>C | 3'Flank (SNP) | VAF 32/72 reads (44%) | catalogued as rs1015954497; called by muse, mutect2, varscan2
- FAT3 | c.*2313T>C | 3'UTR (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- GABRG2 | c.*1583C>T | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- GZF1 | c.*83T>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- H2BP2 | n.276T>G | RNA (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*151G>C | 3'UTR (SNP) | VAF 38/41 reads (93%) | called by muse, mutect2, varscan2
- ISM2 | c.141+47C>T | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs1242213851; called by muse, mutect2
- LRRC38 | c.*482C>G | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- METTL3 | c.-50T>C | 5'UTR (SNP) | VAF 56/187 reads (30%) | catalogued as rs1467535221; called by mutect2, varscan2
- MEX3B | c.*871G>A | 3'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- MS4A15 | c.*522C>A | 3'UTR (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- MSMB | c.*67G>A | 3'UTR (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- PDZRN4 | c.-101G>A | 5'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- PHTF2 | c.1119+198A>T | Intron (SNP) | VAF 62/124 reads (50%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*1859G>C | 3'UTR (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- PLIN4 | c.*1635C>G | 3'UTR (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- POGLUT1 | c.*1640A>T | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PPP5C | c.799-85C>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- PSD3 | c.*4939A>C | 3'UTR (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- RAB29 | chr1:205768895 G>A | 3'Flank (SNP) | VAF 12/35 reads (34%) | catalogued as rs1366022161; called by muse, mutect2, varscan2
- RAB29 | c.*227C>T | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- RABGGTA | c.1147+39G>A | Intron (SNP) | VAF 31/60 reads (52%) | catalogued as rs749916809, COSV52864959; called by muse, mutect2, varscan2
- RBM39 | c.52-373A>G | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- SERPINH1 | c.623-283G>T | Intron (SNP) | VAF 42/81 reads (52%) | catalogued as rs1299076832; called by muse, mutect2, varscan2
- SLC25A36 | c.385+3744T>C | Intron (SNP) | VAF 46/80 reads (58%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*5400T>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- SLC35F6 | c.*1529C>T | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- SNRPA1 | c.460-37C>T | Intron (SNP) | VAF 42/355 reads (12%) | called by muse, mutect2, varscan2
- SRP72 | c.*828A>T | 3'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- STYXL2 | chr1:167128937 T>C | 3'Flank (SNP) | VAF 52/109 reads (48%) | catalogued as rs1056086512; called by muse, mutect2, varscan2
- TBX15 | c.1025-5383T>C | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- TCP11L2 | c.772+1644A>G | Intron (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- TEX261 | c.*1126A>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- THSD4 | c.*3772C>T | 3'UTR (SNP) | VAF 13/88 reads (15%) | catalogued as rs1246421992; called by muse, mutect2, varscan2
- TIGIT | c.*1455T>C | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- TRPS1 | c.*237del | 3'UTR (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- TYSND1 | c.*716A>C | 3'UTR (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- ZNF385C | c.1167+69G>A | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+3334C>G | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
